Somatic mutation profile of tumor specimen MP2PRT-PAPCED-TMP1-A (aliquot MP2PRT-PAPCED-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPCED, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,591 days).
Specimen MP2PRT-PAPCED-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c091c7f-7e18-4154-83af-cbf1397e7771.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPCED-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPCED-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5507dc83-763a-46ff-acd1-6ae48617c6e0

The open-access MAF lists 66 somatic variants for this specimen: 52 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 11, Nonsense Mutation 3, RNA 1, Frame Shift Del 1, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/548 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADGRV1 | c.7502G>C p.S2501T | Missense Mutation (SNP) | VAF 60/602 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs781076230; called by muse, mutect2, varscan2
- BPIFB6 | c.1172C>A p.S391* | Nonsense Mutation (SNP) | VAF 166/415 reads (40%) | catalogued as COSV62754115, COSV62754524; called by muse, mutect2, varscan2
- CFAP61 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55621720; called by muse, mutect2
- COL1A2 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 64/530 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.425); catalogued as rs760490617, COSV51964152; called by muse, mutect2, varscan2
- FOXO1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 262/536 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65425534; called by muse, mutect2, varscan2
- ITPRIP | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 29/571 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99532548; called by muse, mutect2
- JADE3 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 176/408 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs781920545; called by muse, mutect2, varscan2
- MAPT | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 94/450 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52244341; called by muse, mutect2, varscan2
- MPL | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1398260614; called by muse, mutect2
- MYO16 | c.4399G>A p.E1467K | Missense Mutation (SNP) | VAF 78/1091 reads (7%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); catalogued as rs773396664; called by muse, mutect2
- NEURL4 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1301149855; called by muse, mutect2, varscan2
- RAB30 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV52627427; called by muse, mutect2, varscan2
- RALGPS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 135/460 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs201112886, COSV52217859; called by muse, mutect2, varscan2
- RHCG | c.1260C>G p.F420L | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV51515869; called by muse, mutect2
- SALL3 | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 40/1120 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs769002198, COSV73306185; called by muse, mutect2
- SLC2A1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 56/814 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs80359813, CM002406; called by muse, mutect2
- SOWAHC | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 71/658 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as rs541747708; called by muse, mutect2, varscan2
- TBXT | c.474C>T p.I158= | Splice Region (SNP) | VAF 24/294 reads (8%) | catalogued as COSV51617179; called by muse, mutect2
- TRIM58 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 314/661 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs780952897, COSV63570014; called by muse, mutect2, varscan2
- TXNL4B | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs751426685; called by muse, mutect2, varscan2
- UNC5A | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 20/634 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56172168; called by muse, mutect2
- USP53 | c.983G>C p.R328T | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as rs1360185909; called by muse, mutect2, varscan2
- ZNF460 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1284012085; called by muse, mutect2
- ANKRD62 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ARHGAP10 | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 13/468 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- BCCIP | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 43/518 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CENPF | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CLCN4 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 156/254 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPS1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 18/317 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- CTTNBP2 | c.362T>G p.M121R | Missense Mutation (SNP) | VAF 183/404 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPYS | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ELP2 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 176/419 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- IGKV2-30 | c.357del p.W119Cfs*? | Frame Shift Del (DEL) | VAF 55/60 reads (92%) | called by pindel*, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIMS2 | c.520A>C p.T174P (on ENST00000355119 / NM_001161403.3; = p.T198P on NM_017980.4) | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MMP14 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- MMP8 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 205/415 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, varscan2
- NEK1 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- NEURL4 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 75/364 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLD5 | c.662C>T p.S221F (on ENST00000442594; = p.S159F on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2
- PRUNE2 | c.6032C>G p.S2011* | Nonsense Mutation (SNP) | VAF 17/504 reads (3%) | called by muse, mutect2
- PTCH1 | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 28/835 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- PTGDS | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 208/563 reads (37%) | called by muse, mutect2, varscan2
- RPRD2 | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 19/613 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- STX12 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 70/363 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TAB3 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 109/328 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMCO1 | c.115T>C p.S39P | Missense Mutation (SNP) | VAF 183/641 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFRSF10A | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 196/657 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TTN | c.20187C>G p.F6729L (on ENST00000591111; = p.F5802L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/305 reads (17%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WDHD1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- ZSWIM9 | c.1473G>C p.Q491H | Missense Mutation (SNP) | VAF 35/867 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); called by muse, mutect2
- ARL6IP1 | c.87G>A p.V29= | Silent (SNP) | VAF 140/562 reads (25%) | catalogued as COSV58614346; called by muse, mutect2, varscan2
- BCAN | c.429C>T p.I143= | Silent (SNP) | VAF 13/332 reads (4%) | catalogued as COSV61255479; called by muse, mutect2
- EDNRA | c.591G>C p.G197= | Silent (SNP) | VAF 28/526 reads (5%) | called by muse, mutect2
- IL22 | c.222C>G p.L74= | Silent (SNP) | VAF 14/420 reads (3%) | called by muse, mutect2
- MAGEE2 | c.1365G>T p.L455= | Silent (SNP) | VAF 206/652 reads (32%) | catalogued as COSV64898155; called by muse, mutect2, varscan2
- PBX1 | c.21G>A p.L7= | Silent (SNP) | VAF 20/678 reads (3%) | called by muse, mutect2
- PIM2 | c.297G>C p.V99= | Silent (SNP) | VAF 26/681 reads (4%) | called by muse, mutect2
- PPP1R26 | c.2367C>T p.D789= | Silent (SNP) | VAF 272/610 reads (45%) | catalogued as rs777369326; called by muse, varscan2
- STAC3 | c.363G>A p.K121= | Silent (SNP) | VAF 44/287 reads (15%) | called by muse, mutect2, varscan2
- TDRD5 | c.1117C>T p.L373= | Silent (SNP) | VAF 82/234 reads (35%) | catalogued as rs760878417; called by muse, mutect2, varscan2
- ZMYM2 | c.663G>A p.Q221= | Silent (SNP) | VAF 180/431 reads (42%) | called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937679 ins CCG | 3'Flank (INS) | VAF 9/103 reads (9%) | called by mutect2, pindel*
- LINC02606 | n.254dup | RNA (INS) | VAF 111/247 reads (45%) | catalogued as rs1429505343; called by mutect2, varscan2
- TXNL4B | c.*1688G>C | 3'UTR (SNP) | VAF 84/462 reads (18%) | called by muse, mutect2, varscan2
